Somatic mutation profile of tumor specimen TCGA-44-2662-01A (aliquot TCGA-44-2662-01A-01W-0928-08) from TCGA case TCGA-44-2662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-44-2662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fe23d5b-78f2-4d73-9dd0-5ad0247db458.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2662-10A (Blood Derived Normal), aliquot TCGA-44-2662-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b32ea73-bae1-4655-947a-a71d6fa8b08c

The open-access MAF lists 215 somatic variants for this specimen: 164 protein-altering or splice-affecting, 49 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 49, Nonsense Mutation 9, Frame Shift Del 4, Splice Region 4, Frame Shift Ins 3, Nonstop Mutation 2, RNA 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.882C>T p.L294= | Splice Region (SNP) | VAF 31/134 reads (23%) | catalogued as rs63751707, CS086119, COSV51615064; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 13/120 reads (11%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 66/541 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV55951076; called by muse, mutect2, varscan2
- ABCA13 | c.9493G>C p.D3165H | Missense Mutation (SNP) | VAF 64/530 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71284199; called by muse, mutect2, varscan2
- ABCA13 | c.14104G>A p.E4702K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV68944021; called by muse, mutect2, varscan2
- ACTN2 | c.1347C>G p.S449R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100857132, COSV63972620; called by muse, mutect2, varscan2
- AMN | c.163-1G>A p.X55_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54486203; called by muse, mutect2, varscan2
- ANAPC1 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV61974574; called by muse, mutect2
- AP4B1 | c.1775C>A p.S592* | Nonsense Mutation (SNP) | VAF 25/162 reads (15%) | catalogued as COSV56723643, COSV56724960; called by muse, mutect2, varscan2
- ATP11C | c.2737A>T p.M913L | Missense Mutation (SNP) | VAF 112/305 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59560166; called by muse, mutect2, varscan2
- BAX | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV53169282; called by muse, mutect2, varscan2
- BCAS3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs771698366, COSV66770605; called by muse, mutect2, varscan2
- BCHE | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52254138; called by muse, mutect2, varscan2
- BMERB1 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55506397; called by muse, mutect2, varscan2
- BMP2K | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs780640612, COSV58592648; called by muse, mutect2, varscan2
- C12orf56 | c.1270G>C p.E424Q (on ENST00000543942 / NM_001170633.2; = p.E264Q on NM_001099676.3) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61485568, COSV61488362; called by muse, mutect2, varscan2
- C1orf87 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV64596255; called by muse, mutect2, varscan2
- C2orf78 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.127); catalogued as rs1409069598, COSV68516575; called by muse, mutect2, varscan2
- CACNA1B | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV53116343; called by muse, mutect2, varscan2
- CACNA1E | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV62384201; called by muse, mutect2, varscan2
- CCDC146 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53544797; called by muse, mutect2, varscan2
- CCDC88A | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55057407; called by muse, mutect2, varscan2
- CCDC90B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52623501; called by muse, mutect2, varscan2
- CCP110 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66816618; called by muse, mutect2, varscan2
- CETN3 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 94/468 reads (20%) | catalogued as COSV51616945; called by muse, mutect2, varscan2
- CHAMP1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1555379780, COSV63521883; called by muse, mutect2, varscan2
- CNTLN | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV52068519; called by muse, mutect2, varscan2
- CNTN5 | c.1646A>G p.Y549C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54286974; called by muse, mutect2
- COBL | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54339839; called by muse, mutect2, varscan2
- CPS1 | c.4502A>G p.*1501Wext*13 | Nonstop Mutation (SNP) | VAF 127/508 reads (25%) | catalogued as COSV51803674; called by muse, mutect2, varscan2
- CSMD3 | c.10640G>T p.S3547I (on ENST00000297405 / NM_001363185.1; = p.S3378I on NM_052900.3) | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV52116090; called by muse, mutect2, varscan2
- CYFIP2 | c.2231G>T p.S744I (on ENST00000616178 / NM_001291722.2; = p.S719I on NM_014376.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59029806; called by muse, mutect2, varscan2
- DDX27 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV65629139; called by muse, mutect2, varscan2
- DENND1B | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52461557; called by muse, mutect2, varscan2
- DHRS9 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748041645, COSV59139004; called by muse, mutect2
- DKK2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 40/427 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV53394673; called by muse, mutect2
- DNAH10 | c.4962C>G p.I1654M (on ENST00000409039; = p.I1593M on NM_207437.3) | Missense Mutation (SNP) | VAF 164/536 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV68989065, COSV68995673; called by muse, mutect2, varscan2
- DNAJC1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV65409444; called by muse, mutect2, varscan2
- DNAJC14 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54477846; called by muse, mutect2, varscan2
- ERI3 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV64830371; called by muse, mutect2
- EXOC1 | c.838A>G p.M280V | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV62119302; called by muse, mutect2
- EXOG | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55062785; called by muse, mutect2, varscan2
- FLCN | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV53257576; called by muse, mutect2, varscan2
- FMN2 | c.4759T>G p.L1587V | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100144541, COSV60419697; called by muse, mutect2
- FRMD8 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs759320847, COSV53683382; called by muse, mutect2, varscan2
- FSIP2 | c.16905G>C p.K5635N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100554337; called by muse, mutect2, varscan2
- GDAP2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV65611979; called by muse, mutect2
- GOLGA4 | c.6639G>T p.L2213F | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728697; called by muse, mutect2, varscan2
- GOLGA4 | c.6640G>T p.E2214* | Nonsense Mutation (SNP) | VAF 48/333 reads (14%) | catalogued as COSV100728700; called by muse, mutect2, varscan2
- GPATCH1 | c.210A>G p.G70= | Splice Region (SNP) | VAF 7/116 reads (6%) | catalogued as rs1481598464, COSV50111744; called by muse, mutect2
- GPATCH1 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV50111020, COSV50111767, COSV50112587; called by muse, mutect2, varscan2
- GPBP1L1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV51967299; called by muse, mutect2
- GSDMC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 62/444 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs910419404, COSV52692967; called by muse, mutect2, varscan2
- GSDME | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | catalogued as COSV61651075; called by muse, mutect2
- GTF2I | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 31/439 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs145729076; called by muse, mutect2
- GUCY1A2 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 49/466 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as COSV56479596; called by muse, mutect2, varscan2
- HCN1 | c.1708A>T p.N570Y | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV57496403; called by muse, mutect2
- IL1RAPL1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56234164, COSV56241733; called by muse, mutect2, varscan2
- IMPG2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 80/339 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV51974431; called by muse, mutect2, varscan2
- IWS1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as COSV54866847; called by muse, mutect2
- JAKMIP2 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 77/446 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54598719; called by muse, mutect2, varscan2
- KIF26B | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs375797576; called by muse, mutect2, varscan2
- KIN | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65430057; called by muse, mutect2, varscan2
- KLHL15 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60139363; called by muse, mutect2, varscan2
- KLHL3 | c.1578C>A p.C526* | Nonsense Mutation (SNP) | VAF 91/489 reads (19%) | catalogued as COSV59051273, COSV59054767; called by muse, mutect2, varscan2
- KNDC1 | c.4697C>G p.S1566C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757639617, COSV58832188, COSV58841310; called by muse, mutect2, varscan2
- KRTAP23-1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 93/818 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV61935551; called by muse, mutect2, varscan2
- LCAT | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50452188; called by muse, mutect2
- LGALS9 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56348151; called by muse, mutect2, varscan2
- LGR4 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV60820240; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.266); catalogued as COSV53275994, COSV53278487; called by muse, mutect2
- LRRC4C | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs775124868, COSV53419365; called by muse, mutect2
- LYN | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV70205381; called by muse, mutect2, varscan2
- MACF1 | c.5555C>T p.S1852L | Missense Mutation (SNP) | VAF 54/260 reads (21%) | catalogued as COSV57109524; called by muse, mutect2, varscan2
- MAIP1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.741); catalogued as COSV54460280; called by muse, mutect2, varscan2
- MAP3K1 | c.4178C>G p.A1393G | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV68122158; called by muse, mutect2, varscan2
- MCTP1 | c.1515G>C p.K505N | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV56505994; called by muse, mutect2, varscan2
- MMRN1 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53338104, COSV99306646; called by muse, mutect2
- MMUT | c.532C>G p.P178A | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV51272443; called by muse, mutect2, varscan2
- MTBP | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59961276, COSV59961624; called by muse, mutect2, varscan2
- MUC16 | c.18502G>C p.G6168R | Missense Mutation (SNP) | VAF 87/323 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV67449722, COSV67478144; called by muse, mutect2, varscan2
- MYCBP2 | c.4337G>C p.G1446A (on ENST00000357337; = p.G1484A on NM_015057.5) | Missense Mutation (SNP) | VAF 113/390 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62011668; called by muse, mutect2, varscan2
- MYLK2 | c.1409T>C p.V470A | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65658665; called by muse, mutect2, varscan2
- MYMK | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.482); catalogued as COSV60599989, COSV60600171; called by muse, mutect2, varscan2
- N4BP1 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV52209788; called by muse, mutect2, varscan2
- NAV3 | c.6123G>T p.R2041S (on ENST00000397909 / NM_001024383.2; = p.R2019S on NM_014903.6) | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746764163, COSV57065193; called by muse, mutect2
- NCKAP1L | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV53204058; called by muse, mutect2, varscan2
- NIPAL4 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57423918, COSV57430406; called by muse, mutect2, varscan2
- NLRP13 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100738131, COSV61620365; called by muse, mutect2, varscan2
- NOP16 | c.393G>A p.K131= | Splice Region (SNP) | VAF 8/46 reads (17%) | catalogued as COSV51257452; called by muse, mutect2, varscan2
- NPPA | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV56738360; called by muse, mutect2, varscan2
- NUMB | c.981C>G p.I327M (on ENST00000355058; = p.I316M on NM_003744.5) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61828178, COSV61830428; called by muse, mutect2, varscan2
- OLFM4 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54576084; called by muse, mutect2, varscan2
- OR10X1 | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 69/320 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV63767025; called by muse, mutect2, varscan2
- OR2L8 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 127/741 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61725780, COSV61728604; called by muse, mutect2, varscan2
- OR2M4 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60707445; called by muse, mutect2, varscan2
- OR7A5 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59234224; called by muse, varscan2
- OR8G5 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 92/898 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV100422267; called by muse, mutect2
- PCDHA8 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs146582216, COSV65323904; called by muse, mutect2
- PDGFRB | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55801742; called by muse, mutect2, varscan2
- PHKB | c.2737G>C p.D913H | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV54515846; called by muse, mutect2, varscan2
- PIGX | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56359154; called by muse, mutect2, varscan2
- PKHD1L1 | c.7663G>A p.D2555N | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV65737711; called by muse, mutect2, varscan2
- PLCL1 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70822292; called by muse, mutect2
- PLD5 | c.1202C>A p.A401E (on ENST00000442594; = p.A339E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59135609; called by muse, mutect2, varscan2
- PLP1 | c.699C>T p.F233= | Splice Region (SNP) | VAF 100/213 reads (47%) | catalogued as COSV58275720; called by muse, mutect2, varscan2
- PPP2R2A | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60095931; called by muse, mutect2, varscan2
- PPP6R3 | c.2493A>C p.K831N (on ENST00000393800 / NM_001352375.2; = p.K751N on NM_018312.5) | Missense Mutation (SNP) | VAF 258/744 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV55722277; called by muse, mutect2, varscan2
- PREPL | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as COSV53215383; called by muse, mutect2, varscan2
- PTPRZ1 | c.5657C>G p.P1886R | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV66431672; called by muse, mutect2, varscan2
- RIF1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV54613278; called by muse, mutect2, varscan2
- RPL11 | c.296C>T p.S99L (on ENST00000374550 / NM_001199802.1; = p.S100L on NM_000975.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs11556036, COSV65778420; called by muse, mutect2, varscan2
- RPL22 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52377101; called by muse, mutect2, varscan2
- RUFY1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60158676; called by muse, mutect2
- RYR1 | c.11362G>C p.E3788Q | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV62090965, COSV62091055; called by muse, mutect2
- SAMD15 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV53625454; called by muse, mutect2, varscan2
- SBSN | c.1463G>T p.G488V (on ENST00000452271 / NM_001166034.2; = p.G145V on NM_198538.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1408212094, COSV71733065; called by muse, mutect2, varscan2
- SEZ6L | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as COSV50658819; called by muse, mutect2, varscan2
- SLC1A2 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53519140; called by muse, mutect2
- SLC22A8 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs755445118, COSV60324005; called by muse, mutect2
- SLC26A3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs868438571, COSV60639061, COSV60640869; called by muse, mutect2
- SLC38A7 | c.242dup p.V82Rfs*31 | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | catalogued as rs755556671; called by pindel, varscan2
- SLC39A12 | c.1793C>G p.S598C (on ENST00000377369 / NM_001145195.2; = p.S561C on NM_152725.3) | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs765088632, COSV66195699; called by muse, mutect2, varscan2
- SLCO5A1 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV52654919; called by muse, mutect2
- SMAD4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV61685296, COSV61696805; called by muse, mutect2, varscan2
- SMG5 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV62434193, COSV62434555; called by muse, mutect2, varscan2
- SRRM2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57069276; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.917G>C p.*306Sext*1 | Nonstop Mutation (SNP) | VAF 72/363 reads (20%) | catalogued as rs1259641661, COSV60322588; called by muse, mutect2, varscan2
- STAG3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 111/712 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV57928012; called by muse, mutect2, varscan2
- STAT2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149666262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR9 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71512183; called by muse, mutect2
- THAP12 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV52609641, COSV52611941; called by muse, mutect2, varscan2
- TLK2 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as rs777808122, COSV58297734; called by muse, mutect2, varscan2
- TMEM108 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV58865488; called by muse, mutect2, varscan2
- TRA2A | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51715959; called by muse, mutect2, varscan2
- TRBC2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs782153350; called by muse, mutect2, varscan2
- TRHDE | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53835267; called by muse, mutect2, varscan2
- TRIM7 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51240776; called by muse, mutect2
- TRPM7 | c.3053G>T p.R1018I | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57914027; called by muse, mutect2, varscan2
- TSC22D2 | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV62622252; called by muse, mutect2, varscan2
- TSHZ3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.378); catalogued as COSV53665760; called by muse, mutect2
- TTC23 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 23/95 reads (24%) | catalogued as COSV50440833; called by muse, mutect2, varscan2
- TTC8 | c.1374G>A p.M458I (on ENST00000338104 / NM_001288781.1; = p.M442I on NM_144596.4) | Missense Mutation (SNP) | VAF 112/434 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs758330370, COSV57626554; called by muse, varscan2
- TTN | c.11507A>T p.Q3836L (on ENST00000591111; = p.Q3790L on NM_003319.4) | Missense Mutation (SNP) | VAF 79/276 reads (29%) | catalogued as COSV59914943; called by muse, mutect2, varscan2
- TYRO3 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55481275, COSV55487658; called by muse, mutect2, varscan2
- UBAP2 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.366); catalogued as COSV62545428, COSV62548950; called by muse, mutect2, varscan2
- UQCRQ | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51525893; called by muse, mutect2, varscan2
- USP34 | c.3709C>G p.L1237V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV68398939; called by muse, mutect2
- UVRAG | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62101812; called by muse, mutect2, varscan2
- ZBBX | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV56784066; called by muse, mutect2, varscan2
- ZFHX4 | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50551279; called by muse, mutect2, varscan2
- ZNF507 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758381137, COSV61330269; called by muse, mutect2, varscan2
- ZNF546 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV61257303; called by muse, mutect2
- ZNF597 | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV57083674, COSV57085949; called by muse, mutect2, varscan2
- AAR2 | c.431_439delinsGAG p.T144_K147delinsRE | In Frame Del (DEL) | VAF 34/308 reads (11%) | called by pindel, varscan2*
- AHNAK | c.345_357del p.S115Rfs*15 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- CD163 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2
- MFSD8 | c.1271del p.V424Gfs*2 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.4482dup p.E1495* | Frame Shift Ins (INS) | VAF 88/970 reads (9%) | called by mutect2, pindel
- PLEKHG1 | c.1700_1704del p.S567Ffs*10 | Frame Shift Del (DEL) | VAF 36/176 reads (20%) | called by pindel, varscan2
- PTPN20 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIX3 | c.941_942del p.A314Gfs*17 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- ADD3 | c.639C>T p.F213= | Silent (SNP) | VAF 45/185 reads (24%) | catalogued as COSV53320887; called by muse, mutect2, varscan2
- ATN1 | c.930C>G p.L310= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV63110355; called by muse, mutect2
- BCAR1 | c.2238C>T p.F746= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV50779076; called by muse, mutect2, varscan2
- CACNA1B | c.1572C>G p.L524= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV53116322; called by muse, mutect2, varscan2
- CACNA1F | c.723A>T p.A241= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59903314; called by muse, mutect2, varscan2
- CACNG4 | c.981G>T p.V327= | Silent (SNP) | VAF 85/409 reads (21%) | catalogued as COSV50924266; called by muse, mutect2, varscan2
- CCDC87 | c.2034G>A p.L678= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV59578490; called by muse, mutect2, varscan2
- CD59 | c.24C>G p.V8= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV60918993; called by muse, mutect2, varscan2
- CNOT1 | c.3804G>A p.E1268= | Silent (SNP) | VAF 43/250 reads (17%) | catalogued as rs1240474585, COSV55313819; called by muse, mutect2, varscan2
- CPA3 | c.441T>C p.S147= | Silent (SNP) | VAF 55/253 reads (22%) | catalogued as COSV56043997; called by muse, mutect2, varscan2
- CSMD1 | c.7977T>C p.H2659= (on ENST00000520002; = p.H2658= on NM_033225.6) | Silent (SNP) | VAF 110/598 reads (18%) | catalogued as rs1420433528, COSV59289766; called by muse, mutect2, varscan2
- DNAH8 | c.2925G>T p.G975= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV59429556; called by muse, mutect2
- DOCK3 | c.2292C>T p.F764= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1181055200, COSV56504659; called by muse, mutect2, varscan2
- DSTN | c.108C>T p.V36= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV55712305; called by muse, mutect2, varscan2
- ELOVL5 | c.102C>T p.P34= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs374432575; called by muse, mutect2, varscan2
- EVI5 | c.1203C>T p.V401= | Silent (SNP) | VAF 69/379 reads (18%) | catalogued as COSV64825788; called by muse, mutect2, varscan2
- FXR1 | c.834C>T p.F278= | Silent (SNP) | VAF 32/204 reads (16%) | catalogued as COSV59761409; called by muse, mutect2, varscan2
- GARS1 | c.1371G>A p.E457= | Silent (SNP) | VAF 58/332 reads (17%) | catalogued as COSV66827960; called by muse, mutect2, varscan2
- GC | c.138C>A p.V46= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV56735678, COSV99909497; called by muse, mutect2, varscan2
- GPR183 | c.969G>C p.L323= | Silent (SNP) | VAF 44/202 reads (22%) | catalogued as COSV63117180; called by muse, mutect2, varscan2
- HEPH | c.2871T>A p.T957= (on ENST00000343002; = p.T690= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/175 reads (7%) | catalogued as COSV57960036; called by muse, mutect2
- HYI | c.765C>T p.F255= (on ENST00000372434 / NM_001330526.2; = p.F230= on NM_031207.6) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV65094217; called by muse, mutect2, varscan2
- IGSF22 | c.1680G>A p.Q560= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV60031515; called by muse, mutect2
- KLKB1 | c.45T>A p.A15= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV52994258; called by muse, mutect2
- LNPEP | c.2277G>A p.E759= | Silent (SNP) | VAF 61/326 reads (19%) | catalogued as COSV51476664; called by muse, mutect2, varscan2
- LRP1 | c.3468C>T p.T1156= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs1347019663, COSV54503612; called by muse, mutect2, varscan2
- MED12 | c.4134C>G p.L1378= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as COSV61333791; called by muse, mutect2, varscan2
- MED12 | c.4293C>A p.L1431= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV61333804; called by muse, mutect2, varscan2
- MOCS3 | c.600C>T p.L200= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV54865742; called by muse, mutect2, varscan2
- MYCBP2 | c.4287G>C p.L1429= (on ENST00000357337; = p.L1467= on NM_015057.5) | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs377177103, COSV62011678; called by muse, mutect2, varscan2
- OR1C1 | c.867C>A p.I289= | Silent (SNP) | VAF 109/499 reads (22%) | catalogued as COSV68715457; called by muse, mutect2, varscan2
- PCLO | c.2988G>A p.V996= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV61619415; called by muse, mutect2, varscan2
- PCMTD2 | c.564C>T p.V188= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as COSV55059281; called by muse, mutect2, varscan2
- PDPR | c.2310C>T p.F770= | Silent (SNP) | VAF 100/442 reads (23%) | catalogued as COSV55349631; called by muse, mutect2, varscan2
- PKHD1 | c.5166C>T p.I1722= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as COSV61863471; called by muse, mutect2, varscan2
- POLK | c.1197C>T p.S399= | Silent (SNP) | VAF 14/274 reads (5%) | catalogued as COSV54032674; called by muse, mutect2
- POT1 | c.375C>T p.F125= | Silent (SNP) | VAF 125/443 reads (28%) | catalogued as COSV62928375; called by muse, mutect2, varscan2
- PSD3 | c.2758C>T p.L920= (on ENST00000440756; = p.L919= on NM_015310.4) | Silent (SNP) | VAF 55/308 reads (18%) | catalogued as rs377209838, COSV54067396; called by muse, mutect2, varscan2
- PTBP3 | c.567C>G p.L189= | Silent (SNP) | VAF 40/190 reads (21%) | catalogued as COSV52956154; called by muse, mutect2, varscan2
- SLC12A2 | c.492C>T p.V164= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs528719144, COSV52468881; called by muse, mutect2, varscan2
- SLC35B2 | c.1221C>G p.L407= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV51487931; called by muse, mutect2, varscan2
- SLC38A11 | c.951C>A p.L317= (on ENST00000409149 / NM_001351539.1; = p.L295= on NM_173512.2) | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as COSV58052069; called by muse, mutect2
- SZT2 | c.3717C>T p.V1239= (on ENST00000634258 / NM_001365999.1; = p.V1182= on NM_015284.4) | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV65167756; called by muse, mutect2
- TENM1 | c.708C>A p.T236= | Silent (SNP) | VAF 54/346 reads (16%) | catalogued as COSV64426331; called by muse, mutect2, varscan2
- TEX264 | c.360C>T p.F120= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV58133614; called by muse, mutect2, varscan2
- TRRAP | c.723G>A p.L241= | Silent (SNP) | VAF 78/251 reads (31%) | catalogued as COSV62840348, COSV62848788; called by muse, mutect2, varscan2
- ULBP3 | c.684C>G p.L228= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV66253992; called by muse, mutect2, varscan2
- UTRN | c.8820C>G p.L2940= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV62307722; called by muse, mutect2, varscan2
- ZFPM2 | c.969G>A p.V323= | Silent (SNP) | VAF 46/251 reads (18%) | catalogued as COSV65872748; called by muse, mutect2, varscan2
- OR2W5 | n.1042C>A | RNA (SNP) | VAF 67/286 reads (23%) | called by muse, mutect2, varscan2
- SNORD115-3 | n.1G>A | RNA (SNP) | VAF 25/131 reads (19%) | catalogued as rs761103960; called by muse, mutect2, varscan2
